Somatic mutation profile of tumor specimen HCM-BROD-0577-C15-06A (aliquot HCM-BROD-0577-C15-06A-01D-A83U-36) from HCMI case HCM-BROD-0577-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 63.0 years (23,026 days).
Specimen HCM-BROD-0577-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69590d52-2cc9-42c4-9fd0-6b4e99e8f8a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0577-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0577-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f0e8fe0-a453-4586-843c-69f7e3cbc026

The open-access MAF lists 149 somatic variants for this specimen: 104 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 41, Nonsense Mutation 7, Intron 2, 5'Flank 1, Frame Shift Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.1482G>A p.M494I | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.535); catalogued as rs1426558794; called by muse, mutect2
- ADGRL3 | c.874C>T p.R292C (on ENST00000506720 / NM_001322402.2; = p.R224C on NM_015236.6) | Missense Mutation (SNP) | VAF 45/450 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746274680, COSV72268662; called by muse, mutect2, varscan2
- APC | c.4037C>A p.S1346* | Nonsense Mutation (SNP) | VAF 72/557 reads (13%) | catalogued as COSV57325995, COSV57328373, COSV57364395; called by muse, mutect2, varscan2
- ARNT | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs192996355; called by muse, mutect2, varscan2
- BCL11A | c.1612C>T p.R538C (on ENST00000335712 / NM_001365609.1; = p.R572C on NM_018014.4) | Missense Mutation (SNP) | VAF 66/914 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs768167495; called by muse, mutect2
- C8orf34 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 48/936 reads (5%) | SIFT deleterious, low confidence (0); catalogued as rs970911902; called by muse, mutect2
- CEACAM5 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 48/674 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV55751514; called by muse, mutect2
- CNTNAP1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 73/659 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99226467; called by muse, mutect2, varscan2
- DNAH6 | c.9350G>A p.R3117Q | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs992951674, COSV52883193; called by muse, mutect2
- DSEL | c.2877A>C p.Q959H | Missense Mutation (SNP) | VAF 57/510 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.698); catalogued as rs182255712, COSV100025798; called by muse, mutect2, varscan2
- EMILIN2 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs778731918, COSV99598495; called by muse, mutect2, varscan2
- EVC2 | c.3002C>A p.A1001E | Missense Mutation (SNP) | VAF 62/463 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60388197; called by muse, mutect2, varscan2
- FAM222A | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 90/683 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143726568; called by muse, mutect2, varscan2
- FREM3 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 45/756 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV61679162; called by muse, mutect2
- HAS2 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1294249506; called by muse, mutect2
- HSP90B1 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1381329965; called by muse, mutect2
- IER3 | c.416C>G p.S139W | Missense Mutation (SNP) | VAF 55/1145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs762827505; called by muse, mutect2
- IGFALS | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 161/685 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs145465654, COSV51904855; called by muse, mutect2, varscan2
- IKZF2 | c.564G>T p.R188S | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59578633; called by muse, mutect2
- KCNN4 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs778075609; called by muse, mutect2
- LAMA1 | c.7639G>A p.V2547I | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367598361; called by muse, mutect2, varscan2
- MAP3K5 | c.3082C>T p.H1028Y | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.433); catalogued as COSV62890282; called by muse, mutect2
- MTNR1B | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 38/608 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs764536870, COSV57068453; called by muse, mutect2
- NFKB2 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 92/780 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs774941850; called by muse, mutect2, varscan2
- NRK | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV54606532; called by mutect2, varscan2
- NTRK1 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 146/1046 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs764581997, COSV104423323, COSV62323137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR56A4 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 33/593 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs889408530; called by muse, mutect2
- PKLR | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 75/1006 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1336522710, COSV61360721; called by muse, mutect2
- PLSCR4 | c.749G>A p.C250Y | Missense Mutation (SNP) | VAF 44/471 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV100724292; called by muse, mutect2
- PSD2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 52/834 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs201057651; called by muse, mutect2
- RPL27A | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 54/542 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs777153516; called by muse, mutect2
- SLC6A15 | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs1454815811, COSV57029168; called by muse, mutect2
- TATDN2 | c.625C>G p.R209G | Missense Mutation (SNP) | VAF 46/698 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55050469; called by muse, mutect2
- TJP2 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 48/880 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs754080705, COSV55267291; called by muse, mutect2
- TMEM47 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750916621, COSV52067262; called by muse, mutect2, varscan2
- TRPV6 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748307676; called by muse, mutect2
- ZBTB45 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 41/769 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.108); catalogued as rs1184262730; called by muse, mutect2
- ZNF208 | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68107459; called by muse, varscan2
- ZNF211 | c.1117G>A p.E373K (on ENST00000347302 / NM_198855.4; = p.E386K on NM_006385.5) | Missense Mutation (SNP) | VAF 41/753 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs781751403, COSV53743999, COSV99560352; called by muse, mutect2
- ANAPC2 | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 74/740 reads (10%) | called by muse, varscan2
- ARHGAP11B | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ARID1A | c.6436A>T p.K2146* | Nonsense Mutation (SNP) | VAF 107/738 reads (14%) | called by muse, mutect2, varscan2
- ASPM | c.4159G>T p.V1387F | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CCDC168 | c.18383A>T p.K6128M | Missense Mutation (SNP) | VAF 32/397 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCNF | c.1697C>A p.S566* | Nonsense Mutation (SNP) | VAF 30/446 reads (7%) | called by muse, mutect2
- CHIT1 | c.566C>A p.T189N | Missense Mutation (SNP) | VAF 58/510 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CILK1 | c.1450G>C p.D484H (on ENST00000350082 / NM_001375397.1; = p.D477H on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/674 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- CLDN5 | c.206C>T p.S69L (on ENST00000618236 / NM_001363066.2; = p.S154L on NM_003277.4) | Missense Mutation (SNP) | VAF 32/948 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CNST | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 69/492 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTNNA3 | c.2616A>T p.R872S | Missense Mutation (SNP) | VAF 32/693 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- DHRS12 | c.806C>G p.S269C (on ENST00000444610 / NM_001377930.1; = p.S220C on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/1014 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, mutect2
- DMRTA2 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 42/744 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- DPYD | c.2345C>G p.A782G | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2
- FAAP24 | c.577G>C p.G193R | Missense Mutation (SNP) | VAF 48/660 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- FAM117B | c.1657G>C p.A553P | Missense Mutation (SNP) | VAF 52/521 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2
- FBXO8 | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR156 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 39/735 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- GRHL3 | c.1763C>G p.P588R | Missense Mutation (SNP) | VAF 41/684 reads (6%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.811); called by muse, mutect2
- IL11RA | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 43/482 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- INSL6 | c.19T>G p.L7V | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- IRX4 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 74/930 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2
- ITPRIPL2 | c.430C>G p.P144A | Missense Mutation (SNP) | VAF 54/786 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); called by muse, mutect2
- KIFC1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 53/1045 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.147); called by muse, mutect2
- KL | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 54/981 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); called by muse, mutect2
- KRTAP4-11 | c.255C>G p.C85W | Missense Mutation (SNP) | VAF 44/1064 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LAMA1 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 104/644 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRB4 | c.1307C>G p.S436C (on ENST00000391733 / NM_001278428.3; = p.S435C on NM_001278426.3) | Missense Mutation (SNP) | VAF 35/629 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.439); called by muse, mutect2
- MAGEL2 | c.3720C>G p.H1240Q | Missense Mutation (SNP) | VAF 46/526 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); called by muse, mutect2
- MLNR | c.791G>C p.S264T | Missense Mutation (SNP) | VAF 119/961 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MPDU1 | c.453G>C p.L151F | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- MPHOSPH8 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 21/336 reads (6%) | called by muse, mutect2
- MUC16 | c.18406G>A p.E6136K | Missense Mutation (SNP) | VAF 37/557 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.065); called by muse, mutect2
- MUC16 | c.3854C>A p.S1285* | Nonsense Mutation (SNP) | VAF 26/497 reads (5%) | called by muse, mutect2
- MYH7B | c.5714A>G p.D1905G | Missense Mutation (SNP) | VAF 62/502 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- NID1 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.017); called by muse, mutect2
- NTRK2 | c.1870G>C p.D624H (on ENST00000323115 / NM_001369534.1; = p.D640H on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR4C3 | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 67/603 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PIEZO2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); called by muse, mutect2
- PPP1R3F | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM9 | c.1220T>A p.V407E | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2
- PREX1 | c.2015A>G p.N672S | Missense Mutation (SNP) | VAF 53/539 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- RNF213 | c.5089G>A p.E1697K | Missense Mutation (SNP) | VAF 39/670 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.046); called by muse, mutect2
- RPTN | c.1845A>T p.R615S | Missense Mutation (SNP) | VAF 21/528 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2
- SDR16C5 | c.726G>C p.L242F | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2
- SLC16A14 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 34/503 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); called by muse, mutect2
- SLC6A4 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLIT1 | c.3994A>G p.K1332E | Missense Mutation (SNP) | VAF 120/823 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SOX30 | c.1671dup p.A558Cfs*9 | Frame Shift Ins (INS) | VAF 82/662 reads (12%) | called by mutect2, pindel, varscan2
- SP9 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); called by muse, mutect2
- SPATA46 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 37/541 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA5 | c.2581C>T p.H861Y | Missense Mutation (SNP) | VAF 51/412 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- STXBP5L | c.1566G>A p.W522* | Nonsense Mutation (SNP) | VAF 18/317 reads (6%) | called by muse, mutect2
- TCF7 | c.658_662del p.L220Ffs*73 | Frame Shift Del (DEL) | VAF 52/440 reads (12%) | called by mutect2, pindel, varscan2
- THAP1 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 40/600 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAF7 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- TRIM62 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 46/786 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- TRIM64B | c.979T>C p.F327L | Missense Mutation (SNP) | VAF 44/847 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.515); called by muse, mutect2
- TRPM6 | c.4860G>T p.E1620D | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- TRPS1 | c.3281T>C p.L1094P (on ENST00000220888 / NM_001330599.2; = p.L1107P on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/551 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- TTC27 | c.2276A>C p.E759A | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.193); called by muse, mutect2
- VCAN | c.4897A>C p.S1633R | Missense Mutation (SNP) | VAF 48/481 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- ZNF112 | c.2526C>G p.F842L (on ENST00000337401 / NM_001083335.2; = p.F836L on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/613 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF141 | c.1161A>T p.K387N | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2
- ZNF829 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CCDC63 | c.1431G>A p.P477= | Silent (SNP) | VAF 61/634 reads (10%) | catalogued as rs201517807, COSV57527110; called by muse, mutect2
- CDHR5 | c.2013G>A p.A671= (on ENST00000358353 / NM_001171968.2; = p.A677= on NM_021924.5) | Silent (SNP) | VAF 50/1342 reads (4%) | catalogued as rs758394688; called by muse, mutect2
- CDHR5 | c.807G>T p.L269= | Silent (SNP) | VAF 52/706 reads (7%) | called by muse, mutect2
- CECR2 | c.3627G>A p.P1209= (on ENST00000342247 / NM_001290047.2; = p.P1025= on NM_001290046.1) | Silent (SNP) | VAF 39/612 reads (6%) | catalogued as rs367605937; called by muse, mutect2
- CEMIP | c.780C>T p.F260= | Silent (SNP) | VAF 22/442 reads (5%) | called by muse, mutect2
- CYP2D7 | c.1437G>A p.L479= | Silent (SNP) | VAF 40/1328 reads (3%) | catalogued as rs1387908141; called by muse, mutect2
- FJX1 | c.1173C>T p.L391= | Silent (SNP) | VAF 70/1018 reads (7%) | called by muse, mutect2
- GFM2 | c.1953T>G p.T651= | Silent (SNP) | VAF 57/391 reads (15%) | called by muse, mutect2, varscan2
- HDAC5 | c.3069C>A p.L1023= | Silent (SNP) | VAF 25/517 reads (5%) | catalogued as COSV99291183; called by muse, mutect2
- HRNR | c.1239C>T p.R413= | Silent (SNP) | VAF 70/583 reads (12%) | catalogued as rs752238836, COSV64261879; called by muse, mutect2, varscan2
- IPCEF1 | c.1077C>T p.I359= | Silent (SNP) | VAF 41/348 reads (12%) | catalogued as COSV54540511, COSV54548437; called by muse, mutect2, varscan2
- KIF26A | c.1746G>A p.A582= | Silent (SNP) | VAF 42/892 reads (5%) | catalogued as rs915648835; called by muse, mutect2
- LRRC20 | c.162C>A p.L54= | Silent (SNP) | VAF 38/713 reads (5%) | called by muse, mutect2
- LRRC41 | c.162G>A p.V54= | Silent (SNP) | VAF 56/801 reads (7%) | called by muse, mutect2
- MDM1 | c.1512T>C p.S504= | Silent (SNP) | VAF 16/272 reads (6%) | catalogued as rs1246854427; called by muse, mutect2
- MTUS1 | c.3147G>A p.L1049= (on ENST00000262102 / NM_001363061.1; = p.L215= on NM_020749.4) | Silent (SNP) | VAF 40/522 reads (8%) | called by muse, mutect2
- MXRA5 | c.7935C>T p.N2645= | Silent (SNP) | VAF 25/416 reads (6%) | catalogued as COSV54243771; called by muse, mutect2
- MYF6 | c.531G>A p.A177= | Silent (SNP) | VAF 41/429 reads (10%) | catalogued as COSV57353464; called by muse, mutect2
- NLRC5 | c.3924G>A p.L1308= | Silent (SNP) | VAF 73/437 reads (17%) | called by muse, mutect2, varscan2
- OR11G2 | c.339C>A p.T113= | Silent (SNP) | VAF 38/527 reads (7%) | called by muse, mutect2
- PLCD3 | c.399C>T p.F133= | Silent (SNP) | VAF 78/1214 reads (6%) | catalogued as rs962539626, COSV59560962; called by muse, mutect2
- PRODH2 | c.1518G>A p.R506= (on ENST00000301175; = p.R430= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 62/536 reads (12%) | catalogued as rs776588763, COSV56560307; called by muse, mutect2, varscan2
- QPRT | c.201C>A p.L67= | Silent (SNP) | VAF 66/792 reads (8%) | catalogued as COSV54879788; called by muse, mutect2
- RAD21 | c.204C>T p.H68= | Silent (SNP) | VAF 14/430 reads (3%) | catalogued as rs918914974; called by muse, mutect2
- RBM28 | c.2073C>T p.P691= | Silent (SNP) | VAF 42/537 reads (8%) | catalogued as rs770210501, COSV56165037; called by muse, mutect2
- RP1L1 | c.270C>T p.L90= | Silent (SNP) | VAF 21/722 reads (3%) | called by muse, mutect2
- RPL4 | c.126C>T p.T42= | Silent (SNP) | VAF 41/595 reads (7%) | called by muse, mutect2
- RPRD1A | c.822G>C p.L274= | Silent (SNP) | VAF 30/490 reads (6%) | called by muse, mutect2
- RTEL1 | c.1044C>T p.I348= | Silent (SNP) | VAF 47/431 reads (11%) | catalogued as rs762614267; called by muse, mutect2, varscan2
- SEMA5B | c.534T>A p.T178= | Silent (SNP) | VAF 70/542 reads (13%) | called by muse, mutect2, varscan2
- SLC52A2 | c.237C>T p.V79= | Silent (SNP) | VAF 36/678 reads (5%) | catalogued as rs1554853879; called by muse, mutect2
- SPHKAP | c.1011A>C p.A337= | Silent (SNP) | VAF 42/488 reads (9%) | called by muse, mutect2
- TAF4 | c.2277G>A p.T759= | Silent (SNP) | VAF 62/1012 reads (6%) | catalogued as rs1359261096; called by muse, mutect2
- TKFC | c.720C>T p.L240= | Silent (SNP) | VAF 40/628 reads (6%) | called by muse, mutect2
- TLN2 | c.1878G>A p.L626= | Silent (SNP) | VAF 32/466 reads (7%) | called by muse, mutect2
- TONSL | c.1506G>A p.P502= | Silent (SNP) | VAF 80/713 reads (11%) | catalogued as rs779139647; called by muse, mutect2, varscan2
- TTN | c.17148T>C p.A5716= (on ENST00000591111; = p.A4789= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/524 reads (6%) | called by muse, mutect2
- ZC3H11B | c.2271A>T p.R757= | Silent (SNP) | VAF 56/852 reads (7%) | called by muse, mutect2
- ZNF219 | c.1620G>A p.S540= | Silent (SNP) | VAF 52/694 reads (7%) | catalogued as rs763617351; called by muse, mutect2
- ZNF263 | c.1191G>A p.Q397= | Silent (SNP) | VAF 28/478 reads (6%) | called by muse, mutect2
- ZNF71 | c.1050C>T p.G350= | Silent (SNP) | VAF 76/782 reads (10%) | catalogued as rs758955497; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156890 G>A | 3'Flank (SNP) | VAF 67/415 reads (16%) | catalogued as rs767856105; called by muse, mutect2, varscan2
- IL36B | c.261+918C>G | Intron (SNP) | VAF 32/566 reads (6%) | called by muse, mutect2
- LINC02615 | chr4:128466647 G>C | 5'Flank (SNP) | VAF 43/531 reads (8%) | called by muse, mutect2
- NSUN4 | c.94-1236G>A | Intron (SNP) | VAF 21/339 reads (6%) | catalogued as rs962752887; called by muse, mutect2
